Surgical pathology report (de-identified scan), TCGA case TCGA-HP-A5MZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HP-A5MZ-01A (Primary Tumor).

ICD-O-3
Carcinoma, hepatocellular NO.
8170/3
Site: Liver, hepatic
022.0
7/14/13

Sample Number

Sample Type TUMOUR

Diagnosis	Hepatocellular carcinoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	Liver
Tumour Size (cm)	6
Histology	Hepatocellular carcinoma
Grade/Differentiation	II
Pathological T	T1,NOS
Pathological N	NX
Clinical M	M0
Histology Comments	Also found, steatohepatitis, grade 2/3 (moderate activity) stage 1/4 (pericentral fibrosis): moderate macrovesicular fatty change, mild parenchymal and mesenchymal iron overload.

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

Source: NCI Genomic Data Commons file c6c2e4af-7b5b-4e38-8506-a124b8bc5f64 (TCGA-HP-A5MZ.BD5F2C9B-16EE-42B2-B09B-F9BE4FCB2F75.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).